Somatic mutation profile of tumor specimen TCGA-14-1823-01A (aliquot TCGA-14-1823-01A-01D-1494-08) from TCGA case TCGA-14-1823, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.5 years (21,384 days).
Specimen TCGA-14-1823-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbec852b-81ec-4479-a33e-60303c3ab719.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-14-1823-10A (Blood Derived Normal), aliquot TCGA-14-1823-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83cba63a-ed43-434e-ab3e-7731d5485415

The open-access MAF lists 54 somatic variants for this specimen: 45 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 8, Nonsense Mutation 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR8 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770118342, COSV51639089; called by muse, mutect2, varscan2
- ANO7 | c.1708G>A p.V570I (on ENST00000274979; = p.V516I on NM_001370694.2) | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.01); catalogued as rs148576854; called by muse, mutect2, varscan2
- BVES | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV58947380, COSV58950329; called by muse, mutect2
- COBLL1 | c.2864A>G p.Y955C (on ENST00000392717; = p.Y917C on NM_014900.5) | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779338264, COSV52077688; called by muse, mutect2, varscan2
- DDX60 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767373127, COSV67095656; called by muse, mutect2, varscan2
- DGKI | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as rs1259961080, COSV55934682; called by muse, mutect2, varscan2
- EMC1 | c.2741A>G p.Q914R | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV64346821; called by muse, mutect2
- EPHA6 | c.1823A>T p.H608L | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.457); catalogued as COSV101064547, COSV67597166; called by muse, mutect2, varscan2
- ESRRB | c.923A>C p.D308A | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV55068160; called by muse, mutect2, varscan2
- FAM187B | c.700T>A p.C234S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61201859; called by muse, mutect2, varscan2
- FERD3L | c.79C>T p.R27C | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs752444969, COSV51761506; called by muse, mutect2, varscan2
- FLG | c.3668A>G p.D1223G | Missense Mutation (SNP) | VAF 120/717 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs185500015; called by muse, mutect2, varscan2
- FOXP3 | c.617A>T p.K206M | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV66052160; called by muse, mutect2
- FZD1 | c.474A>T p.K158N | Missense Mutation (SNP) | VAF 87/510 reads (17%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.951); catalogued as COSV55313804; called by muse, mutect2, varscan2
- GZMB | c.724A>G p.K242E | Missense Mutation (SNP) | VAF 55/281 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV53543947; called by muse, mutect2, varscan2
- HUWE1 | c.7081G>A p.G2361R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as rs1556943291, COSV53351450; called by muse, mutect2, varscan2
- IGKV1D-16 | c.233G>A p.S78N | Missense Mutation (SNP) | VAF 82/359 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs542346733; called by muse, mutect2, varscan2
- KCNK13 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56418528; called by muse, mutect2
- KCNQ5 | c.473G>T p.S158I | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.122); catalogued as COSV59686504; called by muse, mutect2, varscan2
- LRP12 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.967); catalogued as COSV52635579; called by muse, mutect2, varscan2
- MORC1 | c.2330T>A p.L777H | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51733388; called by muse, mutect2
- MUC17 | c.10679C>G p.T3560S | Missense Mutation (SNP) | VAF 123/626 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV60306834; called by muse, mutect2, varscan2
- NAALADL1 | c.116A>T p.D39V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60526388; called by muse, mutect2, varscan2
- NEU2 | c.950C>T p.A317V | Missense Mutation (SNP) | VAF 62/290 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV52091532; called by muse, mutect2, varscan2
- NKIRAS1 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 44/168 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66248943; called by muse, mutect2, varscan2
- NR0B2 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.417); catalogued as rs750666067, CM142514, COSV54260370; called by muse, mutect2, varscan2
- NUP214 | c.2033C>G p.S678C | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV63913679; called by muse, mutect2, varscan2
- OGG1 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1343218116, COSV56540704; called by muse, mutect2, varscan2
- OR6C6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs757658611, COSV64456046; called by muse, mutect2, varscan2
- PABPC1L | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 89/352 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs772807340, COSV53841283; called by muse, mutect2, varscan2
- PADI6 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs375910439; called by muse, mutect2
- PGAP4 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV66388532; called by muse, mutect2, varscan2
- PSD3 | c.2555T>C p.L852S (on ENST00000440756; = p.L851S on NM_015310.4) | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1489813175, COSV54082200; called by muse, mutect2, varscan2
- RBPJL | c.132-1G>T p.X44_splice | Splice Site (SNP) | VAF 11/59 reads (19%) | catalogued as COSV59216221; called by muse, mutect2, varscan2
- RNF213 | c.803C>G p.A268G | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.567); catalogued as COSV60631381; called by muse, mutect2
- SLC38A1 | c.999C>G p.F333L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV67065139; called by muse, mutect2, varscan2
- SNAI2 | c.657C>A p.N219K | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV50080576; called by muse, mutect2, varscan2
- SPATA31A1 | c.3430C>A p.Q1144K | Missense Mutation (SNP) | VAF 45/325 reads (14%) | SIFT tolerated (0.89); PolyPhen benign (0.101); catalogued as COSV100885083; called by muse, mutect2, varscan2
- SSX1 | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as COSV65355648, COSV65356546; called by muse, mutect2
- TBXT | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs775012230, COSV51616284; called by muse, mutect2, varscan2
- TTN | c.57050C>T p.T19017I (on ENST00000591111; = p.T11593I on NM_003319.4) | Missense Mutation (SNP) | VAF 65/386 reads (17%) | PolyPhen probably damaging (0.951); catalogued as COSV60402440; called by muse, mutect2, varscan2
- UPP1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.467); catalogued as COSV57978849; called by muse, mutect2
- ZFHX4 | c.4212G>C p.L1404F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51500925; called by muse, mutect2, varscan2
- ZIM3 | c.296G>C p.S99T | Missense Mutation (SNP) | VAF 39/281 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.227); catalogued as COSV54147372; called by muse, mutect2, varscan2
- CNTNAP1 | c.1934T>C p.F645S | Missense Mutation (SNP) | VAF 21/263 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.63); called by muse, mutect2
- AR | c.1485C>T p.S495= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101019600; called by muse, mutect2
- CNTNAP5 | c.1998C>T p.A666= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs368582483; called by muse, mutect2, varscan2
- KIF17 | c.2895C>T p.D965= | Silent (SNP) | VAF 53/208 reads (25%) | catalogued as rs528089648, COSV56118862; called by muse, mutect2, varscan2
- NFX1 | c.2598G>A p.P866= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs748822455, COSV59313685; called by muse, mutect2, varscan2
- OTUD6A | c.600C>T p.Y200= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV57973362; called by muse, mutect2
- P2RY10 | c.444C>T p.Y148= | Silent (SNP) | VAF 36/183 reads (20%) | catalogued as rs773170972, COSV50680680, COSV50682260; called by muse, mutect2, varscan2
- TNR | c.615G>A p.P205= | Silent (SNP) | VAF 74/300 reads (25%) | catalogued as rs1030073087, COSV54893067, COSV54896359; called by muse, mutect2, varscan2
- VPS13A | c.2175T>C p.D725= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as COSV62440860; called by muse, mutect2, varscan2
- HERC2P3 | chr15:20457445 C>A | 5'Flank (SNP) | VAF 10/125 reads (8%) | called by muse, mutect2, varscan2
